Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5812, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5812-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

_____d man status post recent left partial nephrectomy for a pathologic stage T1b Nx Mx conventional (clear cell), renal cell carcinoma. _____ The patient has a right renal tumor, which is resected as the current specimen.

PRE-OP DIAGNOSIS: Same.

POST-OP DIAGNOSIS: Same.

_____URE: Right partial nephrectomy.

FINAL DIAGNOSIS:

PARTS 1

AND 2: DEEP TUMOR MARGIN AND ADDITIONAL DEEP TUMOR MARGIN, BIOPSIES –
PORTIONS OF BENIGN FIBROUS TISSUE AND ADIPOSE TISSUE.
NO RENAL PARENCHYMA IDENTIFIED.
NO EVIDENCE OF MALIGNANCY.

PART 3: PORTION OF RIGHT KIDNEY, PARTIAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (clear cell) TYPE, FUHRMAN NUCLEAR GRADE 2-3/4.
- B. MAXIMUM TUMOR DIAMETER IS 4.5 CM.
- C. CARCINOMA IS CONFINED TO THE KIDNEY WITHOUT EXTRACAPSULAR EXTENSION NOR INVOLVEMENT OF THE RENAL SINUS.
- D. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. NON-NEOPLASTIC KIDNEY SHOWS NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY.
- F. ALL SURGICAL RESECTION MARGINS ARE BENIGN.
- G. TNM PATHOLOGIC STAGE: SEE COMMENT AND MICROSCOPIC DESCRIPTION.

PART 4: ELEVENTH RIB, LATERALITY NOT SPECIFIED, EXCISION –

TWO FRAGMENTS OF FLAT BONE CONSISTENT WITH PORTIONS OF RIB WITH NO SPECIFIC GROSS ABNORMALITY (gross diagnosis; see comment).

COMMENT:

Part 3: I am aware that this patient underwent recent left partial nephrectomy for a conventional (clear cell) renal cell carcinoma which was staged as pathologic stage pT1b Nx Mx. If the carcinoma in the right kidney (current resection) is an independent primary, then the pathologic stage of the right renal tumor is pT1b Nx Mx. The possibility that the right and left tumors represent primary and metastatic lesions cannot be entirely excluded, but this is less likely. If requested, mutational genotyping of the left and right tumors may be performed to compare the mutational profiles of these tumors, to more objectively determine whether they are more likely to be independent or related.

Part 4: The specimen part number 4 labeled "eleventh rib" has been subjected to a gross examination only. If it is desired that this specimen be processed for additional studies, particularly microscopic examination, it is suggested that the case pathologist be notified within two weeks of the signout date of this report. This is particularly important as specimens are routinely discarded after a prescribed period of time.

Source: NCI Genomic Data Commons file 8add5fa6-6eb0-417a-90d4-7388ede53a80 (TCGA-B0-5812.2B48A46F-990D-496B-BE26-DC53CB94B79E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).